Somatic mutation profile of tumor specimen C3N-02153-02 (aliquot CPT0118740006) from CPTAC case C3N-02153, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 55.4 years (20,241 days).
Specimen C3N-02153-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ccf9828-9721-4e5d-a027-4cc0b1514a7b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02153-31 (Blood Derived Normal), aliquot CPT0119990002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/15c1df18-22ff-4d8e-b1a4-aabc214cc559

The open-access MAF lists 86 somatic variants for this specimen: 59 protein-altering or splice-affecting, 15 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 15, Intron 5, 5'UTR 3, Nonsense Mutation 2, 3'UTR 2, Frame Shift Ins 1, 5'Flank 1, Splice Region 1, Frame Shift Del 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDK13 | c.2525A>G p.N842S | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs878853160; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- CTNNB1 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 120/654 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs121913409, COSV62687872, COSV62688307, COSV62689938, COSV62711475; ClinVar: other / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANKRD30A | c.1294G>A p.A432T (on ENST00000611781; = p.A376T on NM_052997.2) | Missense Mutation (SNP) | VAF 105/305 reads (34%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.956); catalogued as rs1443657019, COSV64618400; called by muse, mutect2, varscan2
- ASXL2 | c.934C>T p.R312* | Nonsense Mutation (SNP) | VAF 37/87 reads (43%) | catalogued as COSV55456602; called by muse, mutect2, varscan2
- CSNK1A1 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 107/425 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.156); catalogued as rs763536935, COSV55792791; called by muse, mutect2, varscan2
- DNAH17 | c.1451C>T p.S484L | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs144333252; called by muse, mutect2, varscan2
- FBXL7 | c.1426C>T p.R476C | Missense Mutation (SNP) | VAF 63/215 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs1275721257, COSV61648197; called by muse, mutect2, varscan2
- IGHV2OR16-5 | c.8C>T p.T3M | Missense Mutation (SNP) | VAF 42/294 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as rs780442065; called by muse, mutect2, varscan2
- ITGA8 | c.764C>T p.T255M | Missense Mutation (SNP) | VAF 62/195 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587777281, CM140878, COSV65234883; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MEIOC | c.1067G>A p.G356D | Missense Mutation (SNP) | VAF 81/324 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.559); catalogued as rs1568134087; called by muse, mutect2, varscan2
- NEDD4 | c.1361G>A p.R454Q | Missense Mutation (SNP) | VAF 83/231 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs919291836, COSV59058493; called by muse, mutect2, varscan2
- PARP1 | c.1108C>T p.P370S | Missense Mutation (SNP) | VAF 62/698 reads (9%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV64690492; called by muse, mutect2
- PCDHB12 | c.1577G>C p.G526A | Missense Mutation (SNP) | VAF 231/1149 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs782768075, COSV53401868, COSV99507595; called by muse, mutect2, varscan2
- PCNX4 | c.1156A>G p.N386D (on ENST00000406854 / NM_001330177.2; = p.N152D on NM_022495.5) | Missense Mutation (SNP) | VAF 56/170 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs756264737; called by muse, mutect2, varscan2
- PGLS | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 78/338 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.087); catalogued as rs756046118, COSV53115524; called by muse, mutect2
- PRLHR | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs887226869, COSV53303044; called by muse, mutect2, varscan2
- RRBP1 | c.2252G>A p.R751Q (on ENST00000377813 / NM_001365613.2; = p.R318Q on NM_004587.3) | Missense Mutation (SNP) | VAF 26/326 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs772325450; called by muse, mutect2
- SEMA6C | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.354); catalogued as rs150705082; called by muse, mutect2, varscan2
- STARD9 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs541244427; called by muse, mutect2, varscan2
- TNXB | c.5939C>T p.A1980V (on ENST00000647633; = p.A1733V on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV64474796; called by muse, mutect2, varscan2
- UNC13C | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 77/221 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV99524311; called by muse, mutect2, varscan2
- AASS | c.2081G>A p.G694E | Missense Mutation (SNP) | VAF 115/388 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by mutect2, varscan2
- ABCA1 | c.1715G>A p.G572E | Missense Mutation (SNP) | VAF 77/196 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ABCB1 | c.1822G>A p.E608K | Missense Mutation (SNP) | VAF 54/326 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ADCY5 | c.1552G>T p.D518Y | Missense Mutation (SNP) | VAF 61/194 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AMOTL2 | c.2240G>T p.S747I (on ENST00000422605; = p.S748I on NM_016201.4) | Missense Mutation (SNP) | VAF 57/161 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- AMY2B | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 153/534 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANGPTL3 | c.236A>T p.D79V | Missense Mutation (SNP) | VAF 73/190 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGAP1 | c.898+1G>T p.X300_splice | Splice Site (SNP) | VAF 122/356 reads (34%) | called by muse, mutect2, varscan2
- B4GALT7 | c.586_593dup p.Y199Tfs*92 | Frame Shift Ins (INS) | VAF 65/362 reads (18%) | called by mutect2, varscan2
- CASQ1 | c.196G>A p.V66M | Missense Mutation (SNP) | VAF 108/570 reads (19%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- CCR4 | c.958A>G p.K320E | Missense Mutation (SNP) | VAF 59/184 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CDX2 | c.283G>A p.G95S | Missense Mutation (SNP) | VAF 59/174 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- ERN1 | c.2632A>G p.I878V | Missense Mutation (SNP) | VAF 72/254 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- FMN2 | c.818T>C p.L273P | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HECTD3 | c.2107G>A p.V703I | Missense Mutation (SNP) | VAF 156/472 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by mutect2, varscan2
- HES4 | c.301A>G p.S101G | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- ITGAL | c.2294T>A p.I765N | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- KLF5 | c.734A>G p.Q245R | Missense Mutation (SNP) | VAF 89/309 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- LHX4 | c.723G>C p.E241D | Missense Mutation (SNP) | VAF 48/272 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LOX | c.994T>C p.Y332H | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.95); called by muse, mutect2
- LRRFIP1 | c.1442C>T p.A481V (on ENST00000392000 / NM_001137552.2; = p.A457V on NM_004735.4) | Missense Mutation (SNP) | VAF 101/343 reads (29%) | SIFT tolerated (0.92); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MICAL2 | c.4088A>T p.D1363V | Missense Mutation (SNP) | VAF 64/214 reads (30%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MTRF1L | c.293A>G p.N98S | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NOTCH3 | c.3650C>G p.A1217G | Missense Mutation (SNP) | VAF 129/564 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- PAPOLA | c.1460A>T p.H487L | Missense Mutation (SNP) | VAF 55/264 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- PPP4R4 | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- PRKAG1 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 14/294 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.046); called by muse, mutect2
- RBM15B | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 81/231 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- RPS6KA2 | c.126C>T p.G42= | Splice Region (SNP) | VAF 65/238 reads (27%) | called by muse, mutect2, varscan2
- SMTNL1 | c.613G>A p.E205K (on ENST00000399154; = p.E231K on NM_001105565.2) | Missense Mutation (SNP) | VAF 64/201 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- STAC2 | c.1133T>A p.I378N | Missense Mutation (SNP) | VAF 64/188 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- STRBP | c.1946T>A p.L649* | Nonsense Mutation (SNP) | VAF 76/239 reads (32%) | called by muse, mutect2, varscan2
- SYNE2 | c.10048C>G p.Q3350E | Missense Mutation (SNP) | VAF 73/257 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- TCF7L2 | c.115_116del p.R39Gfs*4 | Frame Shift Del (DEL) | VAF 32/258 reads (12%) | called by pindel, varscan2
- TEX15 | c.7324T>C p.F2442L (on ENST00000256246; = p.F2825L on NM_001350162.2) | Missense Mutation (SNP) | VAF 119/375 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- TMEM74 | c.737T>C p.L246P | Missense Mutation (SNP) | VAF 90/279 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TNXB | c.1234G>T p.G412C | Missense Mutation (SNP) | VAF 22/276 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TTN | c.101023G>A p.E33675K (on ENST00000591111; = p.E26251K on NM_003319.4) | Missense Mutation (SNP) | VAF 44/454 reads (10%) | PolyPhen probably damaging (0.994); called by muse, mutect2
- AMOTL2 | c.2241C>T p.S747= (on ENST00000422605; = p.S748= on NM_016201.4) | Silent (SNP) | VAF 58/161 reads (36%) | called by muse, mutect2, varscan2
- B4GALT6 | c.549G>A p.Q183= | Silent (SNP) | VAF 67/148 reads (45%) | called by muse, mutect2, varscan2
- CANT1 | c.345A>C p.T115= | Silent (SNP) | VAF 228/764 reads (30%) | called by muse, mutect2, varscan2
- CDC16 | c.691C>T p.L231= | Silent (SNP) | VAF 84/246 reads (34%) | called by muse, mutect2, varscan2
- CPNE9 | c.585G>A p.T195= | Silent (SNP) | VAF 71/240 reads (30%) | catalogued as rs756393346; called by muse, mutect2, varscan2
- GPR158 | c.288A>T p.R96= | Silent (SNP) | VAF 110/289 reads (38%) | called by muse, mutect2, varscan2
- GTF3A | c.259C>T p.L87= | Silent (SNP) | VAF 39/230 reads (17%) | catalogued as COSV66969638; called by muse, mutect2, varscan2
- PCDHB12 | c.1578G>T p.G526= | Silent (SNP) | VAF 231/1148 reads (20%) | catalogued as rs782552380; called by muse, mutect2, varscan2
- PCDHGA12 | c.855C>T p.D285= | Silent (SNP) | VAF 21/346 reads (6%) | catalogued as COSV52746544; called by muse, mutect2
- RHOF | c.555C>T p.F185= | Silent (SNP) | VAF 58/208 reads (28%) | called by muse, mutect2, varscan2
- SLC25A31 | c.849C>T p.G283= | Silent (SNP) | VAF 57/196 reads (29%) | catalogued as rs907411784, COSV55420218; called by mutect2, varscan2
- STK36 | c.1428C>T p.F476= | Silent (SNP) | VAF 12/206 reads (6%) | called by muse, mutect2
- TLL1 | c.1077C>T p.N359= | Silent (SNP) | VAF 108/325 reads (33%) | catalogued as rs563293641; called by muse, mutect2, varscan2
- ULK1 | c.81C>T p.F27= | Silent (SNP) | VAF 34/108 reads (31%) | catalogued as rs1474246790; called by muse, mutect2, varscan2
- WNK2 | c.3160C>T p.L1054= | Silent (SNP) | VAF 35/214 reads (16%) | catalogued as COSV52956652; called by muse, mutect2, varscan2
- AC009053.1 | n.778C>T | RNA (SNP) | VAF 52/682 reads (8%) | catalogued as rs767864077; called by muse, mutect2
- ADAMTS17 | c.-49G>A | 5'UTR (SNP) | VAF 81/267 reads (30%) | called by muse, mutect2, varscan2
- CFAP57 | c.2247+52_2247+53del | Intron (DEL) | VAF 68/236 reads (29%) | called by mutect2, pindel, varscan2
- EIF3J | c.-25C>G | 5'UTR (SNP) | VAF 113/468 reads (24%) | catalogued as rs1335947201; called by muse, varscan2
- ERLIN2 | c.425-1688_425-1685del | Intron (DEL) | VAF 184/712 reads (26%) | catalogued as rs765026668; called by mutect2, pindel, varscan2
- FOXP2 | c.*246C>A | 3'UTR (SNP) | VAF 8/58 reads (14%) | called by mutect2, varscan2
- IGFN1 | c.1241+1112G>A | Intron (SNP) | VAF 124/606 reads (20%) | catalogued as rs756251166; called by muse, mutect2, varscan2
- PCNP | c.65-182T>A | Intron (SNP) | VAF 51/270 reads (19%) | called by muse, varscan2
- RPS18 | c.-21G>A | 5'UTR (SNP) | VAF 21/244 reads (9%) | catalogued as rs373729309; called by muse, mutect2
- SLC7A10 | c.1016+94C>T | Intron (SNP) | VAF 119/357 reads (33%) | catalogued as rs752482898; called by muse, mutect2, varscan2
- SNORD52 | chr6:31835449 A>G | 5'Flank (SNP) | VAF 34/385 reads (9%) | called by muse, mutect2
- ZNF224 | c.*462G>A | 3'UTR (SNP) | VAF 44/143 reads (31%) | catalogued as COSV53473688; called by muse, mutect2, varscan2
